Somatic mutation profile of tumor specimen C3L-06061-54 (aliquot CPT0326230002) from CPTAC case C3L-06061, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 61.0 years (22,275 days).
Specimen C3L-06061-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 29169da5-5b9a-45b0-b88d-2b837d8e8903.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06061-51 (Buccal Cell Normal), aliquot CPT0326440002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/475c47f0-0acc-437d-832f-a0545a72044a

The open-access MAF lists 13 somatic variants for this specimen: 8 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 5, Silent 5, Nonsense Mutation 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2D | c.16342C>T p.R5448* | Nonsense Mutation (SNP) | VAF 4/64 reads (6%) | catalogued as rs1422752351, CM114906, COSV56418474; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- NRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 31/606 reads (5%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- TP53 | c.493C>T p.Q165* | Nonsense Mutation (SNP) | VAF 173/378 reads (46%) | hotspot (GDC flag); catalogued as rs730882001, COSV52677910, COSV52844585, COSV53637782; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL2A1 | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 271/679 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.708); catalogued as rs201675352, CM160186; called by muse, mutect2, varscan2
- PGA5 | c.766G>A p.V256M | Missense Mutation (SNP) | VAF 176/438 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.328); catalogued as rs199739043; called by muse, mutect2, varscan2
- RPAP3 | c.950T>G p.L317R | Missense Mutation (SNP) | VAF 66/130 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV50041768; called by muse, mutect2, varscan2
- KIR3DL2 | c.995_996del p.K332Ifs*53 | Frame Shift Del (DEL) | VAF 68/316 reads (22%) | called by mutect2, varscan2
- SOX1 | c.770G>A p.S257N | Missense Mutation (SNP) | VAF 119/271 reads (44%) | SIFT tolerated (0.39); PolyPhen benign (0.007); called by muse, varscan2
- ADGRA3 | c.2193G>A p.T731= | Silent (SNP) | VAF 9/263 reads (3%) | catalogued as rs1417781072, COSV51561836; called by muse, mutect2
- DGUOK | c.15C>T p.R5= | Silent (SNP) | VAF 200/451 reads (44%) | catalogued as rs1367381552; called by muse, mutect2, varscan2
- FAM133A | c.468T>A p.S156= | Silent (SNP) | VAF 127/132 reads (96%) | called by muse, mutect2, varscan2
- PCDH11X | c.2487C>T p.F829= | Silent (SNP) | VAF 205/250 reads (82%) | called by muse, mutect2, varscan2
- TENM3 | c.4326C>T p.A1442= | Silent (SNP) | VAF 99/256 reads (39%) | catalogued as rs768468591; called by muse, mutect2, varscan2
